Surgical pathology report (de-identified scan), TCGA case TCGA-BR-6852, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-6852-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

Formatted Path Report

[REDACTED]

Segment of the stomach with the tumor of 12 x 8 cm, with fatty tissue infiltration.
Greater and lesser omentum lymph nodes are soft, hyperemic.
Omentum is hyperemic.

Adenocarcinoma, G3, with perigastric fat infiltration. Fifteen dissected lymph nodes demonstrate sinus histiocytosis, reactive changes of the follicles. Omentum: fibrosis, focal lymphoid infiltration. Surgical margins along the esophagus are free of metastases.

[page 2 of 3]
Tumor Features: Exophytic (polypoid), Tumor Extent: Perigastric fat , Venous Invasion: Absent, Margins: Absent, Treatment Effect:	STOMACH TISSUE CHECKLIST Specimen type: Subtotal gastrectomy Tumor site: Stomach Tumor size: 8 x 0 x 12 cm Tumor features: Exophytic (polypoid) Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Subserosa Lymph nodes: 0/15 positive for metastasis (Greater and lesser omentum 0/15) Lymphatic invasion: Not specified Venous invasion: Absent Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None
--	---

Source: NCI Genomic Data Commons file b2a28a47-4cb2-4b05-b541-ecb3a3fdcd63 (TCGA-BR-6852.C6AC5892-9D86-4B22-862E-02588657B004.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).